Gene-level copy-number profile of specimen HCM-STAN-0777-C25-85S from HCMI case HCM-STAN-0777-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.0 years (24,820 days).
Specimen HCM-STAN-0777-C25-85S: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5ceed937-3bc9-42b9-a712-0485771a029e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0777-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/5a0f7c26-50cf-4e93-834e-a2de6281bc42

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,526; copy number 2: 19,600; copy number 3: 25,397; copy number 4: 11,493; copy number 5: 838; copy number 7: 2; copy number 8: 50.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 52 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:105,959–202,303, 2 genes, copy number 7 (within-gene range 3–7): AC253576.1, ZNF718.
- chr22:41,045,497–42,058,456, 50 genes, copy number 8 (within-gene range 1–8): Y_RNA, AL080243.2, Y_RNA, AL080243.1, MIR1281, EP300, RNU6-375P, AL035658.1, EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889, ZC3H7B, TEF, RNU6-495P, AL008582.1, TOB2, ACO2, PHF5A, POLR3H, AL023553.1, CSDC2, PMM1, DESI1, XRCC6, Y_RNA, SNU13, Z83840.1, RNU6-476P, C22orf46, MEI1, HMGN2P10, RNU6ATAC22P, Y_RNA, CCDC134, SREBF2-AS1, SREBF2, MIR33A, SHISA8, TNFRSF13C, MIR378I, CENPM, LINC00634, SEPTIN3, Z99716.1, WBP2NL, SLC25A5P1.

Autosomal genes at a single copy (total copy number 1): 979. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
